Somatic mutation profile of tumor specimen ALCH-B1XB-TTP1-A (aliquot ALCH-B1XB-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1XB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.3 years (20,930 days).
Specimen ALCH-B1XB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b626d8de-69a5-4c8d-954e-1973c333405f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1XB-NB1-A (Blood Derived Normal), aliquot ALCH-B1XB-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47e821ae-f2e6-47d1-a838-6fb283ca7c8a

The open-access MAF lists 1,971 somatic variants for this specimen: 1,348 protein-altering or splice-affecting, 376 silent, 247 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,171, Silent 376, Intron 126, Nonsense Mutation 84, RNA 40, Splice Site 35, Frame Shift Del 34, 5'UTR 30, 5'Flank 22, 3'UTR 20, Splice Region 15, 3'Flank 9.

Variants (750 of 1,971; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.3173-1G>A p.X1058_splice | Splice Site (SNP) | VAF 58/332 reads (17%) | catalogued as rs397515875; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.12448C>T p.R4150C (on ENST00000262304 / NM_001009944.3; = p.R4149C on NM_000296.4) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282668884, CM074420, COSV51915679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 72/172 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.1055A>G p.H352R | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1172013361; called by muse, mutect2, varscan2
- AASS | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 88/785 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750821357; called by muse, mutect2, varscan2
- ABCA6 | c.4427C>T p.A1476V | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs760596501; called by muse, mutect2, varscan2
- AC009779.3 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1342886795, COSV57726202; called by muse, mutect2, varscan2
- AC134980.2 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV60906563; called by muse, mutect2, varscan2
- AC136428.1 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 113/337 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV71169188; called by muse, mutect2, varscan2
- AC244197.3 | c.905A>T p.N302I | Missense Mutation (SNP) | VAF 94/182 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV61712884; called by muse, mutect2, varscan2
- ACOT11 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV59347296; called by muse, mutect2, varscan2
- ACP4 | c.778+1del | Frame Shift Del (DEL) | VAF 64/276 reads (23%) | catalogued as rs1568465550, COSV54518422; called by mutect2, pindel, varscan2
- ADAMTS12 | c.2947A>G p.R983G | Missense Mutation (SNP) | VAF 156/543 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs1471441463; called by muse, mutect2, varscan2
- ADCY10 | c.4168+1G>A p.X1390_splice | Splice Site (SNP) | VAF 182/661 reads (28%) | catalogued as rs996858935; called by muse, mutect2, varscan2
- ADCY6 | c.1413G>T p.M471I | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57167658; called by muse, mutect2, varscan2
- ADGRA1 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs530856061; called by muse, mutect2, varscan2
- ADGRG7 | c.1784A>G p.N595S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs774889102; called by muse, mutect2, varscan2
- ADGRL3 | c.2166G>C p.W722C (on ENST00000506720 / NM_001322402.2; = p.W654C on NM_015236.6) | Missense Mutation (SNP) | VAF 48/343 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72230704; called by muse, mutect2, varscan2
- ADH1A | c.937C>A p.R313S | Missense Mutation (SNP) | VAF 54/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52924575; called by muse, mutect2, varscan2
- ADM | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1201356245; called by muse, mutect2, varscan2
- ADSL | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 274/618 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as CM068483; called by muse, mutect2, varscan2
- AGAP1 | c.2294G>T p.G765V (on ENST00000304032 / NM_001037131.3; = p.G712V on NM_014914.5) | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384784289; called by muse, varscan2
- ALK | c.3626G>A p.R1209Q | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs747643140, COSV101201977, COSV66557012; called by muse, mutect2, varscan2
- AP5B1 | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.537); catalogued as rs916853731; called by muse, mutect2, varscan2
- APEX2 | c.1258G>C p.A420P | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58190349; called by muse, mutect2, varscan2
- APOB | c.4202C>A p.S1401Y | Missense Mutation (SNP) | VAF 67/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51936527; called by muse, mutect2, varscan2
- APOBR | c.2977G>T p.V993L (on ENST00000431282; = p.V1002L on NM_018690.4) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV60493474; called by muse, mutect2, varscan2
- APPL1 | c.475-1G>T p.X159_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV55699564; called by muse, mutect2, varscan2
- AQP10 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61474756; called by muse, mutect2, varscan2
- ARHGAP29 | c.676G>T p.V226F | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99558705; called by muse, varscan2
- ARHGAP31 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs752955355, COSV51795950; called by muse, mutect2, varscan2
- ARHGAP36 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV52263844, COSV52263848, COSV52271862; called by muse, mutect2, varscan2
- ARHGAP42 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100081179; called by muse, mutect2, varscan2
- ARHGEF11 | c.4550C>T p.A1517V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.223); catalogued as rs777420412, COSV59354684; called by muse, mutect2, varscan2
- ARID4A | c.2181G>T p.L727F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs934764631; called by muse, varscan2
- ASB2 | c.783C>A p.Y261* | Nonsense Mutation (SNP) | VAF 70/322 reads (22%) | catalogued as rs763332972, COSV60114135; called by muse, mutect2, varscan2
- ASB2 | c.449C>A p.P150Q | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60111275; called by muse, mutect2, varscan2
- ATAD2B | c.2737A>C p.N913H | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV53208000; called by muse, varscan2
- ATF5 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV61312085; called by muse, mutect2, varscan2
- ATP2A3 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 124/333 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1252620249; called by muse, mutect2, varscan2
- ATP6V0D2 | c.61C>G p.R21G | Missense Mutation (SNP) | VAF 110/612 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53415469; called by muse, mutect2, varscan2
- ATXN2L | c.3158G>T p.G1053V | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as rs1290865282; called by muse, mutect2, varscan2
- B3GALT1 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59908301; called by muse, mutect2, varscan2
- BAHCC1 | c.4160G>A p.S1387N | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs782393100; called by muse, mutect2, varscan2
- BCR | c.1702G>T p.V568L | Missense Mutation (SNP) | VAF 167/379 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.609); catalogued as rs775046221; called by muse, mutect2, varscan2
- BEND6 | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as rs770761945; called by muse, varscan2
- BMPER | c.1364A>G p.H455R | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV51820941; called by muse, mutect2, varscan2
- BNIP5 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 234/938 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs756258415, COSV71325518; called by muse, mutect2, varscan2
- BRD1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 119/250 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53458624, COSV53461430; called by muse, mutect2, varscan2
- C2orf73 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as rs758034955; called by muse, varscan2
- C3orf33 | c.205C>G p.P69A (on ENST00000340171 / NM_001308229.2; = p.P26A on NM_173657.2) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs757715285; called by muse, mutect2, varscan2
- CACNA1H | c.3655G>T p.G1219W | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746322724, COSV61988148; called by muse, mutect2, varscan2
- CAPS2 | c.963C>G p.D321E | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs1387815236; called by muse, mutect2, varscan2
- CATSPERB | c.1457del p.G486Efs*21 | Frame Shift Del (DEL) | VAF 61/250 reads (24%) | catalogued as COSV56421443; called by mutect2, pindel, varscan2
- CCDC27 | c.1190G>T p.R397M | Missense Mutation (SNP) | VAF 121/386 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV53898380; called by muse, mutect2, varscan2
- CD163L1 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs745392950; called by muse, mutect2, varscan2
- CD1E | c.710C>A p.P237Q | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63770304; called by muse, mutect2, varscan2
- CD33 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); catalogued as rs895532285; called by muse, mutect2, varscan2
- CD3E | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 138/683 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs780235352, COSV62345395; called by muse, varscan2
- CD44 | c.563G>T p.S188I | Missense Mutation (SNP) | VAF 184/580 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs370420547; called by muse, mutect2, varscan2
- CD93 | c.1342G>T p.G448W | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849355; called by muse, mutect2, varscan2
- CFAP47 | c.8329G>T p.D2777Y | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV66215643; called by muse, mutect2, varscan2
- CFAP91 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV56341201; called by muse, mutect2, varscan2
- CFHR2 | c.743C>A p.T248K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs772571537; called by muse, mutect2, varscan2
- CHAMP1 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as rs1555379421; called by muse, mutect2, varscan2
- CHD5 | c.4286G>T p.R1429L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52419764; called by muse, mutect2, varscan2
- CHST13 | c.306C>A p.D102E | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100081474; called by muse, mutect2, varscan2
- CLIP2 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56274053, COSV56280691; called by muse, mutect2, varscan2
- CNGA3 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 225/885 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs767083685, CM148778; called by muse, mutect2, varscan2
- COL4A1 | c.1213G>C p.G405R | Missense Mutation (SNP) | VAF 135/403 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65432716; called by muse, mutect2, varscan2
- COL6A5 | c.3740C>G p.A1247G | Missense Mutation (SNP) | VAF 136/517 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55209835; called by muse, mutect2, varscan2
- COL6A5 | c.6178C>A p.R2060S (on ENST00000312481; = p.R2056S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs139500009, COSV55209104; called by muse, mutect2, varscan2
- CORO1C | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54596356; called by muse, mutect2, varscan2
- CPNE8 | c.1673A>T p.H558L | Missense Mutation (SNP) | VAF 99/390 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV58844472; called by muse, mutect2, varscan2
- CPS1 | c.2644C>A p.R882S | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as rs148519116; called by muse, mutect2, varscan2
- CRACD | c.2058C>A p.S686R | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.236); catalogued as rs768705327, COSV51732358; called by muse, mutect2, varscan2
- CRACD | c.2570G>T p.R857L | Missense Mutation (SNP) | VAF 87/360 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761888500; called by muse, mutect2, varscan2
- CRP | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 158/678 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV54813586; called by muse, mutect2, varscan2
- CRYBG2 | c.3524C>A p.A1175D | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV100366939; called by muse, mutect2, varscan2
- CSMD3 | c.4326G>T p.M1442I (on ENST00000297405 / NM_001363185.1; = p.M1338I on NM_052900.3) | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as COSV52100079; called by mutect2, varscan2
- CST11 | c.341A>G p.N114S (on ENST00000377009 / NM_130794.2; = p.N79S on NM_080830.3) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs1252866045; called by muse, mutect2
- CT47B1 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV64891526, COSV64891542; called by muse, mutect2, varscan2
- CYP4F2 | c.1314+1G>T p.X438_splice | Splice Site (SNP) | VAF 62/179 reads (35%) | catalogued as COSV99686000; called by muse, mutect2, varscan2
- DAD1 | c.173C>G p.S58W | Missense Mutation (SNP) | VAF 60/397 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51663966; called by muse, mutect2, varscan2
- DCAF13 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV52574603; called by muse, mutect2, varscan2
- DCLK3 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1205176501; called by muse, mutect2, varscan2
- DEFB116 | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 88/435 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs370931855; called by muse, mutect2, varscan2
- DHX57 | c.2567G>T p.G856V | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455797610; called by muse, varscan2
- DIDO1 | c.6046C>A p.P2016T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV56613945; called by muse, mutect2, varscan2
- DKK1 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 103/355 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as COSV64760156; called by muse, mutect2, varscan2
- DLG5 | c.1274G>C p.R425P | Missense Mutation (SNP) | VAF 66/423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64950379; called by muse, mutect2, varscan2
- DLGAP4 | c.550A>T p.S184C | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100211771; called by muse, mutect2, varscan2
- DMRTB1 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 43/155 reads (28%) | catalogued as COSV65113183; called by muse, mutect2, varscan2
- DNAH6 | c.1106A>T p.Y369F | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1428749225; called by muse, mutect2, varscan2
- DNAI2 | c.1039C>A p.R347S | Missense Mutation (SNP) | VAF 191/404 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV56757634; called by muse, mutect2, varscan2
- DOLPP1 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 44/123 reads (36%) | catalogued as rs774266763; called by muse, mutect2, varscan2
- DRD5 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774074172; called by muse, mutect2, varscan2
- DTX4 | c.689C>G p.P230R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV57095550; called by muse, mutect2, varscan2
- DYNC1H1 | c.5002G>T p.E1668* | Nonsense Mutation (SNP) | VAF 192/546 reads (35%) | catalogued as COSV64142493; called by muse, mutect2, varscan2
- DYSF | c.3688G>T p.D1230Y | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50271232; called by muse, mutect2, varscan2
- DYSF | c.4548G>T p.E1516D | Missense Mutation (SNP) | VAF 147/575 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV50531302; called by muse, mutect2, varscan2
- ECHS1 | c.358T>G p.W120G | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100881933; called by muse, mutect2, varscan2
- EFCAB7 | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as rs1228928975, COSV64314325; called by muse, mutect2, varscan2
- EIF2AK1 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 207/619 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52237738; called by muse, mutect2, varscan2
- EIF4B | c.1773C>G p.S591R | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.056); catalogued as rs181115836; called by muse, mutect2, varscan2
- ELAPOR2 | c.747G>C p.M249I (on ENST00000450689 / NM_001142749.3; = p.M82I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV99788478; called by muse, mutect2, varscan2
- EMSY | c.1604C>T p.T535M | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1218646757; called by muse, mutect2, varscan2
- ENTHD1 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57318141, COSV57320234, COSV57323027; called by muse, mutect2, varscan2
- EPHA5 | c.917G>T p.R306I | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.282); catalogued as COSV56638183; called by muse, mutect2, varscan2
- EPX | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs750422182, COSV56599166; called by muse, mutect2, varscan2
- ERN1 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 118/251 reads (47%) | catalogued as COSV70504694; called by muse, mutect2, varscan2
- EVC | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 107/360 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99381319; called by muse, mutect2, varscan2
- EVX2 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 138/578 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as rs1238292705; called by muse, mutect2, varscan2
- FAM135B | c.1861G>T p.G621* | Nonsense Mutation (SNP) | VAF 107/399 reads (27%) | catalogued as COSV52740710; called by muse, mutect2, varscan2
- FAM180A | c.110G>T p.R37M | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs141853731; called by muse, mutect2, varscan2
- FAM181A | c.559C>G p.P187A | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as rs972841524, COSV50887805; called by muse, mutect2, varscan2
- FAM181B | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283544541; called by muse, mutect2, varscan2
- FAM186A | c.485T>C p.L162S | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1189585881; called by muse, mutect2, varscan2
- FAT1 | c.4892C>A p.A1631E | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV71674405; called by muse, mutect2, varscan2
- FAT3 | c.8395G>A p.D2799N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); catalogued as COSV53121896, COSV99959708; called by muse, mutect2, varscan2
- FBLN1 | c.1972G>T p.G658C | Missense Mutation (SNP) | VAF 305/586 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100591458; called by muse, mutect2, varscan2
- FBN1 | c.4663G>C p.V1555L | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV57317240; called by muse, mutect2, varscan2
- FBN3 | c.4667G>T p.R1556L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs773094791, COSV54468944; called by muse, mutect2, varscan2
- FBN3 | c.2759G>T p.R920L | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV104374157; called by muse, mutect2, varscan2
- FCHSD2 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 97/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201284616; called by muse, mutect2, varscan2
- FLG2 | c.3980C>A p.S1327Y | Missense Mutation (SNP) | VAF 77/353 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV66169900; called by muse, mutect2, varscan2
- FMO2 | c.1100C>G p.A367G | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV99269034; called by muse, mutect2, varscan2
- FN3KRP | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751950406; called by muse, mutect2, varscan2
- FOLR3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV61530650; called by muse, mutect2, varscan2
- GAB3 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 159/321 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV65820617, COSV65820776; called by muse, mutect2, varscan2
- GABBR2 | c.2120C>A p.A707D | Missense Mutation (SNP) | VAF 233/640 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52296198; called by muse, mutect2, varscan2
- GALNT7 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1157260622; called by muse, mutect2, varscan2
- GCC2 | c.4951G>A p.E1651K | Missense Mutation (SNP) | VAF 121/983 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768992646; called by muse, mutect2, varscan2
- GCK | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.97); catalogued as rs1300199281; called by muse, mutect2, varscan2
- GOLGA6L2 | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as rs1424971658; called by muse, mutect2, varscan2
- GOLGB1 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100510409; called by muse, varscan2
- GPR32 | c.338C>G p.A113G | Missense Mutation (SNP) | VAF 189/623 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as rs779724333; called by muse, mutect2, varscan2
- GPR61 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs951217511; called by muse, mutect2, varscan2
- GPR83 | c.1023C>A p.N341K | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358842142; called by muse, mutect2, varscan2
- GRID2 | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 80/602 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56233204; called by muse, mutect2, varscan2
- GRID2 | c.384G>T p.R128S | Missense Mutation (SNP) | VAF 80/609 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV56240061; called by muse, mutect2, varscan2
- GRID2 | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs758779402, COSV56175461; called by muse, mutect2, varscan2
- GRIN2B | c.3993G>T p.M1331I | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV74207174; called by muse, mutect2, varscan2
- GSX2 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 91/665 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1293371224; called by muse, mutect2
- HABP2 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs1160437288; called by muse, mutect2, varscan2
- HCK | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52946354; called by muse, mutect2, varscan2
- HCN3 | c.409T>C p.F137L | Missense Mutation (SNP) | VAF 100/491 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV64233932; called by muse, mutect2, varscan2
- HEATR5A | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66344954; called by muse, mutect2, varscan2
- HMCN1 | c.9049G>T p.G3017C | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772406590; called by muse, mutect2, varscan2
- HNRNPUL2 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57132690; called by muse, mutect2, varscan2
- HOXD12 | c.587G>C p.G196A | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs768766133; called by muse, mutect2
- HOXD9 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243402412; called by muse, mutect2, varscan2
- HPS5 | c.1781C>T p.T594I (on ENST00000349215 / NM_181507.2; = p.T480I on NM_007216.4) | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61687406; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1214A>C p.D405A | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV52378906; called by muse, mutect2, varscan2
- HSD3B2 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 117/640 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as COSV65593036; called by muse, mutect2, varscan2
- HSPA12A | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV65022107; called by muse, mutect2, varscan2
- HSPG2 | c.9355G>A p.E3119K | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs779581302, COSV101013472; called by muse, mutect2, varscan2
- HTRA3 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1466876815; called by muse, mutect2, varscan2
- HYDIN | c.15121C>A p.P5041T | Missense Mutation (SNP) | VAF 144/440 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs541573051; called by muse, mutect2, varscan2
- HYDIN | c.11472-1G>T p.X3824_splice | Splice Site (SNP) | VAF 43/117 reads (37%) | catalogued as rs751267820; called by muse, mutect2, varscan2
- IGKV1-5 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 207/773 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs770438280; called by muse, mutect2, varscan2
- IGSF11 | c.877T>G p.C293G (on ENST00000393775 / NM_001015887.3; = p.C292G on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs759822063, COSV61165836; called by muse, mutect2, varscan2
- IGSF11 | c.88G>T p.G30W (on ENST00000393775 / NM_001015887.3; = p.G29W on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61172530; called by muse, mutect2, varscan2
- IL16 | c.2350C>A p.P784T (on ENST00000302987 / NM_172217.5; = p.P83T on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57269335; called by muse, mutect2, varscan2
- IL1R1 | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 108/546 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs1390085378; called by muse, mutect2, varscan2
- IL1R2 | c.15C>A p.Y5* | Nonsense Mutation (SNP) | VAF 71/356 reads (20%) | catalogued as rs371324309; called by muse, mutect2, varscan2
- IL2RA | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 145/528 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs765403608; called by muse, mutect2, varscan2
- IMPDH1 | c.1274G>C p.S425T (on ENST00000470772 / NM_001142573.2; = p.S511T on NM_000883.4) | Missense Mutation (SNP) | VAF 57/480 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.555); catalogued as COSV100118877; called by muse, mutect2, varscan2
- INHBA | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV54221694; called by muse, varscan2
- IQGAP3 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 70/387 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs761273643; called by muse, mutect2, varscan2
- ISM1 | c.203C>A p.P68Q | Missense Mutation (SNP) | VAF 128/550 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV52607536; called by muse, mutect2, varscan2
- ITGA7 | c.1399G>T p.A467S (on ENST00000555728; = p.A423S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/451 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV57701314; called by muse, mutect2, varscan2
- ITGB1BP2 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52135721; called by muse, mutect2, varscan2
- JADE2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV50923515; called by muse, mutect2, varscan2
- KCNMB2 | c.24del p.T9Pfs*32 | Frame Shift Del (DEL) | VAF 38/270 reads (14%) | catalogued as COSV64201378; called by pindel, varscan2
- KCNN1 | c.386G>T p.W129L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as rs1411147610; called by muse, mutect2, varscan2
- KCNRG | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 80/215 reads (37%) | catalogued as COSV53949300; called by muse, mutect2, varscan2
- KEAP1 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV50260393; called by muse, mutect2, varscan2
- KIAA1109 | c.7436G>T p.R2479I | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52685595; called by muse, mutect2, varscan2
- KIF2B | c.172del p.V58* | Frame Shift Del (DEL) | VAF 199/578 reads (34%) | catalogued as COSV99276062; called by mutect2, pindel, varscan2
- KIF2B | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 180/442 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs915905631; called by muse, mutect2, varscan2
- KL | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV66310475; called by muse, mutect2, varscan2
- KLHL4 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV100909837; called by muse, mutect2, varscan2
- KMT2D | c.8160G>A p.W2720* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as CM1410246; called by muse, mutect2, varscan2
- KNDC1 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs535222925; called by muse, mutect2, varscan2
- KPRP | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV64221770; called by muse, mutect2, varscan2
- KRT12 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs1469212401; called by muse, mutect2, varscan2
- KRT16 | c.708C>A p.D236E | Missense Mutation (SNP) | VAF 173/397 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs555754233; called by muse, mutect2, varscan2
- KRT6C | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 178/746 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776931101; called by muse, mutect2
- KRT84 | c.1346A>G p.Q449R | Missense Mutation (SNP) | VAF 99/342 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1565774706; called by muse, mutect2, varscan2
- KRTAP13-4 | c.381C>G p.Y127* | Nonsense Mutation (SNP) | VAF 58/260 reads (22%) | catalogued as COSV61879006; called by muse, mutect2, varscan2
- LAYN | c.649G>T p.E217* (on ENST00000375615 / NM_001258390.1; = p.E209* on NM_178834.5) | Nonsense Mutation (SNP) | VAF 30/175 reads (17%) | catalogued as COSV65105280; called by muse, mutect2, varscan2
- LIG1 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.055); catalogued as rs779139031; called by muse, mutect2, varscan2
- LILRB2 | c.964C>A p.R322S | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as rs768452192; called by muse, mutect2, varscan2
- LILRB2 | c.532C>G p.R178G | Missense Mutation (SNP) | VAF 123/441 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV58744033, COSV58745403; called by muse, mutect2, varscan2
- LMX1A | c.1012C>A p.L338M | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV54217692, COSV54226500; called by muse, mutect2, varscan2
- LPIN3 | c.2364C>A p.N788K | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241124989, COSV60038297; called by muse, mutect2, varscan2
- LRIT2 | c.1489C>A p.L497M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs1174489831; called by muse, mutect2
- LRP1B | c.8791T>A p.L2931M | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV101260568; called by muse, varscan2
- LRRC36 | c.589G>C p.G197R | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as COSV52081727, COSV99338550; called by muse, mutect2, varscan2
- LRRC52 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 66/408 reads (16%) | catalogued as COSV54232822; called by muse, mutect2, varscan2
- LRRC7 | c.3452T>A p.L1151Q (on ENST00000651989 / NM_001370785.2; = p.L1118Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50543164; called by muse, mutect2, varscan2
- LRRC9 | c.202del p.E68Kfs*5 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as COSV54292164; called by pindel, varscan2
- LRRIQ3 | c.574-1G>T p.X192_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100598664; called by muse, mutect2, varscan2
- LY75 | c.4700-1G>T p.X1567_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as COSV99716679; called by muse, mutect2, varscan2
- MAGEB2 | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs373920316; called by muse, mutect2, varscan2
- MAGEB6 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV66872276, COSV66872702; called by muse, mutect2, varscan2
- MAGEL2 | c.530C>A p.T177N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); catalogued as rs1039431104; called by muse, mutect2, varscan2
- MAGI1 | c.4140G>C p.Q1380H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs756058727; called by muse, mutect2, varscan2
- MALRD1 | c.4537G>T p.D1513Y | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779885771; called by muse, mutect2, varscan2
- MALSU1 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1320038756, COSV54978460; called by muse, mutect2, varscan2
- MCM3AP | c.2306C>G p.S769C | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99387380; called by muse, mutect2, varscan2
- MEN1 | c.197G>T p.S66I | Missense Mutation (SNP) | VAF 93/324 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs867960556, CX983277; called by muse, mutect2, varscan2
- MIPEP | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs751536805; called by muse, mutect2, varscan2
- MKX | c.844C>A p.L282M | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as COSV65391885; called by muse, mutect2
- MMP26 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs770471115; called by muse, mutect2, varscan2
- MOV10L1 | c.2893-1G>T p.X965_splice | Splice Site (SNP) | VAF 22/33 reads (67%) | catalogued as COSV104393259; called by muse, mutect2, varscan2
- MRC1 | c.1939C>A p.P647T | Missense Mutation (SNP) | VAF 65/569 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554841524; called by muse, mutect2, varscan2
- MTURN | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.648); catalogued as rs1270568437; called by muse, mutect2, varscan2
- MTUS2 | c.2494C>A p.P832T | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV54985665; called by muse, mutect2, varscan2
- MUC16 | c.25679C>A p.S8560Y | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as rs757804475, COSV67477061, COSV67487606; called by muse, mutect2, varscan2
- MUC5AC | c.15394G>T p.V5132F | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT tolerated, low confidence (0.06); catalogued as COSV100611662, COSV64369247; called by muse, mutect2, varscan2
- MUC7 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 130/649 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV100512442; called by muse, varscan2
- NAA11 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV54514347, COSV54516285; called by muse, mutect2, varscan2
- NALCN | c.1028C>A p.T343N | Missense Mutation (SNP) | VAF 109/309 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as rs1365066023; called by muse, mutect2, varscan2
- NAT16 | c.312+7C>A | Splice Region (SNP) | VAF 12/52 reads (23%) | catalogued as rs768574870; called by muse, mutect2, varscan2
- NAT8 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200757014; called by muse, mutect2, varscan2
- NEBL | c.499G>C p.V167L | Missense Mutation (SNP) | VAF 79/575 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs767732816, COSV101008945; called by muse, mutect2, varscan2
- NEGR1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as rs148707586; called by muse, mutect2, varscan2
- NF2 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 185/388 reads (48%) | catalogued as CM002818, COSV58519935; called by muse, mutect2, varscan2
- NIPBL | c.5045G>T p.R1682L | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV56948323; called by muse, mutect2, varscan2
- NLRP2 | c.1579G>A p.G527S | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.181); catalogued as rs371453526; called by muse, mutect2, varscan2
- NLRP3 | c.2810C>A p.P937H | Missense Mutation (SNP) | VAF 116/481 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100276030; called by muse, mutect2, varscan2
- NOTCH2 | c.7340G>T p.G2447V | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.44); catalogued as rs757543412, COSV56691296, COSV56704689; called by muse, mutect2, varscan2
- NPHS2 | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 142/609 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.251); catalogued as COSV62634859; called by muse, mutect2, varscan2
- NR2C1 | c.214A>T p.T72S | Missense Mutation (SNP) | VAF 144/371 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV58008702; called by muse, mutect2, varscan2
- NRF1 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 109/320 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV56211786; called by muse, mutect2, varscan2
- NRG3 | c.2034C>A p.S678R (on ENST00000404547 / NM_001370084.1; = p.S654R on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/462 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100930340; called by muse, mutect2, varscan2
- NRXN1 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs547546408; called by muse, mutect2, varscan2
- NT5DC3 | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs541146599; called by muse, mutect2, varscan2
- NTNG1 | c.933C>A p.S311R | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs1345578070, COSV53972606; called by muse, mutect2, varscan2
- NXPE4 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.169); catalogued as COSV100970580, COSV100970593; called by muse, mutect2, varscan2
- OPN3 | c.527G>T p.W176L | Missense Mutation (SNP) | VAF 210/785 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59363290; called by muse, mutect2, varscan2
- OR10G4 | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 79/387 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100304641; called by muse, mutect2, varscan2
- OR13G1 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs776565972, COSV62944463; called by muse, mutect2, varscan2
- OR14J1 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV65845543; called by muse, mutect2, varscan2
- OR2A25 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV68716883, COSV68717463; called by muse, mutect2, varscan2
- OR2A5 | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV68738992; called by muse, mutect2, varscan2
- OR2L8 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61726860; called by muse, mutect2, varscan2
- OR2M2 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV62897947; called by muse, mutect2, varscan2
- OR2T10 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 92/406 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as rs773297333; called by muse, mutect2, varscan2
- OR2T34 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV60900222; called by muse, mutect2, varscan2
- OR4C13 | c.681del p.L228* | Frame Shift Del (DEL) | VAF 73/261 reads (28%) | catalogued as COSV73648745; called by mutect2, pindel, varscan2
- OR4C15 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV58952824; called by muse, mutect2, varscan2
- OR4C46 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 134/553 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV60218781; called by muse, mutect2, varscan2
- OR4C6 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 94/374 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.378); catalogued as rs763521348, COSV100051639, COSV58603342, COSV58603558; called by muse, mutect2, varscan2
- OR4F6 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); catalogued as COSV100186793; called by muse, mutect2, varscan2
- OR4N2 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 88/575 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763016138, COSV60050143; called by muse, mutect2, varscan2
- OR56B1 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 108/333 reads (32%) | catalogued as COSV99061116; called by muse, mutect2, varscan2
- OR5D14 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 80/437 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV59456819; called by muse, mutect2, varscan2
- OR5H14 | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV71194535; called by muse, varscan2
- OR5H15 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 74/268 reads (28%) | catalogued as COSV62947779; called by muse, varscan2
- OR5H15 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 42/208 reads (20%) | catalogued as rs1246232266; called by muse, varscan2
- OR5T2 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1239817790; called by muse, mutect2, varscan2
- OR5T3 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57381819; called by muse, varscan2
- OR6N2 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV104411280; called by muse, mutect2, varscan2
- OR9G1 | c.476C>A p.T159N | Missense Mutation (SNP) | VAF 84/670 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56454129; called by muse, mutect2
- OTOL1 | c.1075C>G p.P359A | Missense Mutation (SNP) | VAF 148/556 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100019806, COSV60006681; called by muse, mutect2, varscan2
- OTX2 | c.313C>G p.Q105E (on ENST00000408990 / NM_172337.3; = p.Q113E on NM_021728.4) | Missense Mutation (SNP) | VAF 202/749 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.101); catalogued as CM110390; called by muse, mutect2, varscan2
- PAPPA2 | c.4172G>T p.G1391V | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1303498403; called by muse, mutect2, varscan2
- PARP10 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as rs1056503809; called by muse, mutect2, varscan2
- PAWR | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1156923618; called by muse, varscan2
- PCDHA7 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 160/616 reads (26%) | catalogued as COSV65347119; called by muse, varscan2
- PCDHB3 | c.1381C>A p.R461S | Missense Mutation (SNP) | VAF 205/610 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as COSV50586567; called by muse, mutect2, varscan2
- PCK1 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 124/315 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1568909904, COSV60127091; called by muse, mutect2, varscan2
- PDE3B | c.982A>T p.I328F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1178287831; called by muse, mutect2, varscan2
- PGA3 | c.103C>G p.R35G | Missense Mutation (SNP) | VAF 100/604 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100337347; called by muse, mutect2, varscan2
- PGR | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs1365162762; called by muse, mutect2, varscan2
- PIGA | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs769125619; called by muse, mutect2, varscan2
- PIWIL1 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 45/159 reads (28%) | catalogued as COSV55346709; called by muse, varscan2
- PIWIL4 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 84/333 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV54408870; called by muse, mutect2, varscan2
- PKD1L1 | c.2293G>T p.V765L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56972115; called by muse, mutect2
- PKHD1 | c.11997G>T p.W3999C | Missense Mutation (SNP) | VAF 172/549 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs1157546180; called by muse, mutect2, varscan2
- PKHD1 | c.10907A>G p.Q3636R | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100943160; called by muse, mutect2, varscan2
- PKHD1L1 | c.6602C>A p.T2201K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs1023203713; called by muse, mutect2, varscan2
- PLA1A | c.1307C>G p.P436R | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV99845782; called by muse, mutect2, varscan2
- PLEC | c.7558G>C p.E2520Q (on ENST00000322810 / NM_201380.4; = p.E2410Q on NM_000445.5) | Missense Mutation (SNP) | VAF 103/247 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV100516041, COSV100518327; called by muse, mutect2, varscan2
- PLG | c.422C>A p.T141K | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51986042; called by muse, mutect2, varscan2
- PNLIPRP3 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 25/277 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100982483, COSV65048755; called by muse, mutect2, varscan2
- PNPLA1 | c.488C>A p.P163Q (on ENST00000394571 / NM_001374623.1; = p.P68Q on NM_173676.2) | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100463990, COSV57236657; called by muse, mutect2, varscan2
- POP7 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 142/526 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs200306601; called by muse, mutect2, varscan2
- POTEH | c.72G>T p.M24I | Missense Mutation (SNP) | VAF 172/712 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); catalogued as rs371073280; called by muse, varscan2
- PPP1R16B | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55379469; called by muse, mutect2, varscan2
- PPP1R3A | c.3192C>A p.N1064K | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV99493335; called by muse, mutect2
- PRAMEF27 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 127/349 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs1424017692; called by muse, mutect2, varscan2
- PRLHR | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV53305269; called by muse, mutect2, varscan2
- PRM2 | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 120/357 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV54113755; called by muse, mutect2, varscan2
- PROKR2 | c.1103G>T p.R368I | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV54086389; called by muse, mutect2, varscan2
- PROX1 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1175483145, COSV99798988; called by muse, mutect2, varscan2
- PRR23B | c.727G>C p.G243R | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.983); catalogued as rs745967431, COSV61493086; called by muse, mutect2, varscan2
- PRRC2B | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs1429327661; called by muse, mutect2, varscan2
- PRSS55 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV60808672; called by muse, mutect2, varscan2
- PSG4 | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 125/465 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV54939964; called by muse, mutect2, varscan2
- PTCD1 | c.1856C>A p.P619Q | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs374595581; called by muse, mutect2, varscan2
- PTPN21 | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV60850770; called by muse, mutect2, varscan2
- PTPRC | c.3796G>T p.G1266C | Missense Mutation (SNP) | VAF 110/477 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV100722185; called by muse, mutect2, varscan2
- PTPRU | c.4184C>T p.T1395M | Missense Mutation (SNP) | VAF 53/389 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100111392; called by muse, mutect2, varscan2
- PXDNL | c.2783C>A p.P928H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.209); catalogued as COSV62485097, COSV62494635; called by muse, mutect2, varscan2
- PXT1 | c.250A>T p.M84L | Missense Mutation (SNP) | VAF 159/541 reads (29%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as rs1209899834; called by muse, mutect2, varscan2
- RANBP2 | c.3277A>G p.I1093V | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs775993005; called by muse, mutect2, varscan2
- RANBP6 | c.2461G>T p.V821L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV52391023; called by muse, mutect2, varscan2
- RB1 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57324319; called by muse, mutect2, varscan2
- RBM46 | c.1472C>A p.P491H | Missense Mutation (SNP) | VAF 82/299 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs777619985; called by muse, mutect2, varscan2
- RD3 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 112/430 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65362964; called by muse, mutect2, varscan2
- RDH13 | c.679G>C p.A227P (on ENST00000415061 / NM_001145971.2; = p.A156P on NM_138412.4) | Missense Mutation (SNP) | VAF 81/332 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV52560630; called by muse, mutect2, varscan2
- RETREG3 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV58703073; called by muse, mutect2, varscan2
- RGS6 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV59592981; called by muse, varscan2
- RNF128 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs1027258409; called by muse, mutect2, varscan2
- RNF150 | c.1179C>A p.D393E | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761038881, COSV100153456; called by muse, mutect2, varscan2
- ROBO1 | c.147C>G p.N49K | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as COSV71970443; called by muse, mutect2, varscan2
- RP1 | c.216G>C p.R72S | Missense Mutation (SNP) | VAF 198/950 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV99607454; called by muse, mutect2, varscan2
- RP1L1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); catalogued as rs200743572; called by muse, mutect2, varscan2
- RPF1 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs989875097; called by muse, mutect2, varscan2
- RPTN | c.63del p.N22Mfs*12 | Frame Shift Del (DEL) | VAF 79/373 reads (21%) | catalogued as COSV60168383; called by mutect2, pindel, varscan2
- RSAD2 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65908735; called by muse, mutect2
- RUSC1 | c.2255G>A p.R752Q (on ENST00000368352 / NM_001105203.2; = p.R283Q on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/403 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as rs370599994; called by muse, mutect2, varscan2
- RYR1 | c.3667G>T p.E1223* | Nonsense Mutation (SNP) | VAF 186/699 reads (27%) | catalogued as COSV62110858; called by muse, varscan2
- RYR1 | c.8198G>T p.G2733V | Missense Mutation (SNP) | VAF 136/620 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193922828, CM055513; ClinVar: uncertain significance; called by muse, varscan2
- RYR2 | c.3970G>T p.G1324W | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.161); catalogued as COSV63695114; called by muse, mutect2, varscan2
- SALL1 | c.3942C>A p.F1314L | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.294); catalogued as COSV51754596; called by muse, mutect2, varscan2
- SAMD4B | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.017); catalogued as rs750167797; called by muse, mutect2, varscan2
- SAP130 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV99385478; called by muse, mutect2, varscan2
- SCN3A | c.5175C>A p.D1725E | Missense Mutation (SNP) | VAF 166/615 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV51807689; called by muse, mutect2, varscan2
- SCRIB | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs769393665, COSV57590578; called by muse, mutect2, varscan2
- SERPINI1 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1280904922; called by muse, mutect2, varscan2
- SEZ6L | c.1161G>C p.Q387H | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50657934; called by muse, varscan2
- SFRP1 | c.735G>T p.K245N | Missense Mutation (SNP) | VAF 152/446 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1460022173; called by muse, mutect2, varscan2
- SI | c.1332T>G p.Y444* | Nonsense Mutation (SNP) | VAF 78/340 reads (23%) | catalogued as COSV100013991; called by muse, varscan2
- SLC16A9 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 109/373 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV68100772; called by muse, mutect2, varscan2
- SLC17A1 | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55077833; called by muse, mutect2, varscan2
- SLC1A7 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.642); catalogued as COSV65194690; called by muse, mutect2, varscan2
- SLC22A11 | c.1381C>A p.R461= | Splice Region (SNP) | VAF 43/154 reads (28%) | catalogued as COSV57251569; called by muse, mutect2, varscan2
- SLC22A12 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 102/351 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374743769, CM1511163; called by muse, mutect2, varscan2
- SLC22A24 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as rs1311332580; called by muse, mutect2, varscan2
- SLC35E1 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as rs989936448; called by muse, mutect2, varscan2
- SLC4A2 | c.2047G>T p.G683W | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766348973; called by muse, mutect2, varscan2
- SLC5A9 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99361989; called by muse, mutect2, varscan2
- SLC7A10 | c.1418C>G p.P473R | Missense Mutation (SNP) | VAF 99/483 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53504845; called by muse, mutect2, varscan2
- SLC7A3 | c.277C>A p.R93S | Missense Mutation (SNP) | VAF 121/252 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.169); catalogued as COSV53226661; called by muse, mutect2, varscan2
- SLCO1A2 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56608323; called by muse, mutect2, varscan2
- SLIT3 | c.3556-1G>C p.X1186_splice | Splice Site (SNP) | VAF 19/60 reads (32%) | catalogued as rs1355084675; called by muse, mutect2
- SLITRK4 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV100567454; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>A p.T910K | Missense Mutation (SNP) | VAF 128/380 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV60785486, COSV60802491; called by muse, mutect2, varscan2
- SMPDL3A | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs150400180; called by muse, mutect2, varscan2
- SNRPN | c.647C>A p.P216Q | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV57597975; called by muse, mutect2, varscan2
- SORCS3 | c.2608G>T p.A870S | Missense Mutation (SNP) | VAF 56/460 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.177); catalogued as rs367942325, COSV100863627; called by muse, mutect2, varscan2
- SPAG6 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs573352808, COSV100510625, COSV57624523; called by muse, mutect2, varscan2
- SPOCD1 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as rs150345186; called by muse, mutect2, varscan2
- SSH3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1431725015; called by muse, mutect2, varscan2
- STAM | c.873G>C p.E291D | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs201039968; called by muse, mutect2, varscan2
- STIMATE | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as rs760255234, COSV100753756, COSV61890708; called by muse, mutect2, varscan2
- STK36 | c.3436G>T p.A1146S | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.679); catalogued as COSV99831951; called by muse, mutect2, varscan2
- STRA8 | c.395C>A p.A132D (on ENST00000275764; = p.A110D on NM_182489.2) | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs201416012; called by muse, mutect2, varscan2
- STXBP5L | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1378028263; called by muse, mutect2, varscan2
- SUSD3 | c.557+1G>T p.X186_splice | Splice Site (SNP) | VAF 46/115 reads (40%) | catalogued as COSV64937282; called by muse, mutect2, varscan2
- SYCP1 | c.2037G>T p.L679F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.908); catalogued as COSV65696480; called by muse, varscan2
- SYNE2 | c.18661G>A p.E6221K | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs781623552; called by muse, mutect2, varscan2
- TAMALIN | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV99530951; called by muse, mutect2, varscan2
- TBC1D1 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 73/450 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as rs147361950; called by muse, varscan2
- TCP10L2 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1442676494; called by mutect2, varscan2
- TENM2 | c.2440T>C p.C814R (on ENST00000518659 / NM_001122679.2; = p.C582R on NM_001080428.3) | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV69126654; called by muse, mutect2, varscan2
- TENM2 | c.4795G>A p.D1599N (on ENST00000518659 / NM_001122679.2; = p.D1360N on NM_001080428.3) | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766417441; called by muse, mutect2, varscan2
- TEX15 | c.2774C>G p.S925C (on ENST00000256246; = p.S1308C on NM_001350162.2) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.723); catalogued as COSV56348178; called by muse, mutect2, varscan2
- THSD7B | c.283C>G p.R95G | Missense Mutation (SNP) | VAF 117/499 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99744093, COSV99746547; called by muse, mutect2, varscan2
- THSD7B | c.1074G>T p.L358F | Missense Mutation (SNP) | VAF 124/653 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.251); catalogued as rs781353178, COSV55731514; called by muse, varscan2
- THSD7B | c.2171C>A p.P724H | Missense Mutation (SNP) | VAF 86/379 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55696168; called by muse, mutect2, varscan2
- TMEM196 | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs771129901; called by muse, mutect2, varscan2
- TNXB | c.8524G>A p.E2842K (on ENST00000647633; = p.E2595K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.388); catalogued as rs374803743; called by muse, mutect2, varscan2
- TOPAZ1 | c.4205T>C p.I1402T | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs896539221, COSV59068211; called by muse, varscan2
- TPX2 | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV55917699; called by muse, mutect2
- TRHDE | c.2593G>T p.D865Y | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99672769; called by muse, varscan2
- TRIM29 | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as rs924078119, COSV59282083; called by muse, mutect2, varscan2
- TRIM51GP | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 116/335 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.462); catalogued as rs763102477; called by muse, mutect2, varscan2
- TRPA1 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs752350043; called by muse, varscan2
- TRPA1 | c.993G>T p.V331= | Splice Region (SNP) | VAF 36/180 reads (20%) | catalogued as COSV100084734; called by muse, varscan2
- TSHZ3 | c.1822C>A p.H608N | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.954); catalogued as COSV53680772; called by muse, mutect2, varscan2
- TTC34 | c.2156G>T p.R719L | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV69003441, COSV99081320; called by muse, mutect2, varscan2
- TTC37 | c.2704-1G>T p.X902_splice | Splice Site (SNP) | VAF 88/252 reads (35%) | catalogued as rs1360088202; called by muse, mutect2, varscan2
- TTN | c.31725A>T p.K10575N (on ENST00000591111; = p.K9648N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/162 reads (26%) | PolyPhen benign (0.196); catalogued as COSV100622887, COSV100626412; called by muse, mutect2, varscan2
- UBD | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 203/685 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100589691; called by muse, mutect2, varscan2
- UBE4B | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 146/559 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99477538; called by muse, mutect2, varscan2
- UGT3A1 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV57102149; called by muse, mutect2, varscan2
- UNC79 | c.5741G>T p.G1914V (on ENST00000393151 / NM_001346218.2; = p.G1737V on NM_020818.5) | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV56388932; called by muse, mutect2, varscan2
- UNC80 | c.836C>A p.S279Y | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1225594380; called by muse, mutect2, varscan2
- UNK | c.1721C>G p.S574* | Nonsense Mutation (SNP) | VAF 42/116 reads (36%) | catalogued as COSV53142580, COSV53142955; called by muse, mutect2, varscan2
- USH2A | c.7540A>T p.N2514Y | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777618162, COSV100244007, COSV100244096; called by muse, mutect2, varscan2
- USH2A | c.2810-1G>A p.X937_splice | Splice Site (SNP) | VAF 33/182 reads (18%) | catalogued as rs778336512; called by muse, mutect2
- VCAN | c.2540C>A p.T847N | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54107811; called by muse, mutect2, varscan2
- VTCN1 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as COSV60223697; called by muse, mutect2, varscan2
- VWDE | c.4505G>T p.G1502V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV51730310; called by muse, mutect2, varscan2
- WDFY4 | c.6492G>T p.E2164D | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55436739; called by muse, mutect2, varscan2
- WIPI2 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 49/360 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs916597059; called by muse, mutect2, varscan2
- ZAN | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 90/581 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.26); catalogued as COSV61806521, COSV61814249; called by muse, mutect2, varscan2
- ZBBX | c.86G>C p.R29P | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV56794402; called by muse, mutect2, varscan2
- ZBTB9 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as rs771693572; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1064C>G p.S355* | Nonsense Mutation (SNP) | VAF 118/411 reads (29%) | catalogued as COSV99648982; called by muse, mutect2, varscan2
- ZDHHC24 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60081110; called by muse, mutect2, varscan2
- ZFHX4 | c.4441C>A p.H1481N | Missense Mutation (SNP) | VAF 80/461 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV50507661; called by muse, mutect2, varscan2
- ZFP36L1 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100322958; called by muse, mutect2, varscan2
- ZNF280A | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 90/193 reads (47%) | catalogued as COSV100131023; called by muse, mutect2, varscan2
- ZNF326 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 72/372 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs758210031; called by muse, mutect2, varscan2
- ZNF492 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 36/159 reads (23%) | catalogued as rs748642885; called by muse, mutect2, varscan2
- ZNF534 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 93/393 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV56516228; called by muse, mutect2, varscan2
- ZNF653 | c.1466A>C p.N489T | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1337519168, COSV99542092; called by muse, mutect2, varscan2
- ZNF707 | c.491G>T p.R164I | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as COSV62311597; called by muse, mutect2, varscan2
- ZNF804A | c.3470C>A p.P1157H | Missense Mutation (SNP) | VAF 109/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56435888, COSV56452072; called by muse, mutect2, varscan2
- ZNF804B | c.2974G>T p.D992Y | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV60819598; called by muse, mutect2, varscan2
- ZNF835 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs771556208; called by muse, mutect2, varscan2
- AAK1 | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 103/501 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ABCA5 | c.1999G>T p.V667L | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCB1 | c.1762C>G p.R588G | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ABCB5 | c.3163G>T p.G1055W (on ENST00000404938 / NM_001163941.2; = p.G610W on NM_178559.6) | Missense Mutation (SNP) | VAF 110/452 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC11 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCG2 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, varscan2
- ABRAXAS2 | c.666dup p.V223Sfs*6 | Frame Shift Ins (INS) | VAF 44/356 reads (12%) | called by mutect2, pindel, varscan2
- AC023055.1 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC100868.1 | c.1253C>A p.A418D | Missense Mutation (SNP) | VAF 240/618 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, varscan2
- AC100868.1 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 68/180 reads (38%) | called by muse, mutect2, varscan2
- ACE | c.2368T>C p.W790R | Missense Mutation (SNP) | VAF 168/393 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM2A | c.1068C>G p.D356E (on ENST00000219054; = p.D277E on NM_001308169.2) | Missense Mutation (SNP) | VAF 112/277 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADA | c.161A>T p.K54M | Missense Mutation (SNP) | VAF 137/565 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ADAMTS12 | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADAMTS12 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 136/668 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS13 | c.104A>T p.Q35L | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ADAMTS19 | c.2764C>A p.L922I | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS20 | c.4989G>T p.W1663C | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS20 | c.4566G>T p.Q1522H | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, varscan2
- ADAMTSL3 | c.4682C>A p.A1561D | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ADCY2 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF2 | c.2077G>C p.D693H | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRG4 | c.6915G>T p.M2305I | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRL3 | c.2863C>A p.L955M (on ENST00000506720 / NM_001322402.2; = p.L887M on NM_015236.6) | Missense Mutation (SNP) | VAF 67/468 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADGRV1 | c.10351A>T p.S3451C | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ADGRV1 | c.12427G>T p.G4143C | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ADGRV1 | c.17466G>C p.L5822F | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, varscan2
- AGA | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGL | c.4030G>T p.D1344Y | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- AGXT2 | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 199/842 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AHI1 | c.3340G>C p.E1114Q | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, varscan2
- AK2 | c.295G>T p.G99* (on ENST00000354858; = p.G141* on NM_001625.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/442 reads (10%) | called by muse, mutect2, varscan2
- AKR7L | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALG6 | c.481T>G p.Y161D | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- ALS2 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 90/416 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AMBRA1 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANK2 | c.9C>A p.N3K | Missense Mutation (SNP) | VAF 91/643 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ANK2 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 74/500 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ANKRD1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 142/556 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.103); called by muse, varscan2
- ANKRD17 | c.7195G>T p.A2399S | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.042); called by muse, mutect2
- ANKRD30B | c.1408C>G p.H470D | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANKRD35 | c.2513C>A p.T838N | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ANKRD44 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ANKRD44 | c.558G>T p.L186F | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ANKRD54 | c.161C>A p.S54* | Nonsense Mutation (SNP) | VAF 108/193 reads (56%) | called by muse, mutect2, varscan2
- ANKS1A | c.1290G>C p.L430F | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ANKS1A | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO4 | c.458C>A p.S153Y (on ENST00000392977 / NM_001286615.2; = p.S118Y on NM_178826.4) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ANO5 | c.2261A>T p.D754V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AOX1 | c.2648C>A p.S883* | Nonsense Mutation (SNP) | VAF 26/157 reads (17%) | called by muse, mutect2, varscan2
- ARFGAP3 | c.380A>T p.K127M | Missense Mutation (SNP) | VAF 120/258 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- ARG1 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP30 | c.200+1G>T p.X67_splice | Splice Site (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.385G>T p.G129* | Nonsense Mutation (SNP) | VAF 79/336 reads (24%) | called by muse, mutect2, varscan2
- ARMH2 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 135/505 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ARPP21 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- ASB5 | c.115A>T p.S39C | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ASMT | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ASPM | c.7479G>T p.M2493I | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ASPM | c.1559G>T p.C520F | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ASXL3 | c.6542G>T p.G2181V | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ATAD2B | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.244); called by muse, varscan2
- ATAD2B | c.353C>G p.S118* | Nonsense Mutation (SNP) | VAF 44/178 reads (25%) | called by muse, mutect2
- ATAD5 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, varscan2
- ATP10D | c.1015+1G>A p.X339_splice | Splice Site (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- ATP1A3 | c.1994C>A p.A665D (on ENST00000545399 / NM_001256214.2; = p.A652D on NM_152296.5) | Missense Mutation (SNP) | VAF 142/493 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V1B2 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- ATRX | c.7030G>T p.A2344S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BAAT | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 126/324 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAZ2A | c.2470A>T p.T824S | Missense Mutation (SNP) | VAF 105/379 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- BBS12 | c.1741G>T p.A581S | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- BCL7B | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 113/442 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BDP1 | c.2736G>C p.R912S | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- BEGAIN | c.1732C>A p.R578S | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BICD2 | c.1782G>T p.E594D | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BIRC7 | c.817G>C p.A273P (on ENST00000217169 / NM_139317.3; = p.A255P on NM_022161.4) | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- BNC2 | c.1728A>T p.L576F | Missense Mutation (SNP) | VAF 111/384 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- BRD8 | c.1931A>G p.E644G (on ENST00000254900 / NM_139199.2; = p.E717G on NM_006696.4) | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- BTBD17 | c.989_991delinsTT p.P330Lfs*66 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by pindel, varscan2*
- BUB3 | c.971+1G>T p.X324_splice | Splice Site (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- C12orf56 | c.1714A>T p.S572C (on ENST00000543942 / NM_001170633.2; = p.S412C on NM_001099676.3) | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C12orf65 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 170/452 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- C1QC | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C1QTNF7 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- C4orf54 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- C8orf34 | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C9 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 172/684 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C9orf78 | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CA1 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 104/631 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CABIN1 | c.5596G>T p.V1866L | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.97); called by muse, varscan2
- CABP1 | c.697G>C p.A233P (on ENST00000316803 / NM_001033677.1; = p.A30P on NM_004276.5) | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CABS1 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CACHD1 | c.1727A>G p.N576S | Missense Mutation (SNP) | VAF 63/295 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CACNA1F | c.5890G>C p.E1964Q | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- CACNA1G | c.4457A>G p.D1486G | Missense Mutation (SNP) | VAF 215/477 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA2D1 | c.1921C>A p.Q641K (on ENST00000356253 / NM_001366867.1; = p.Q622K on NM_000722.4) | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- CACNA2D3 | c.1238C>A p.A413D | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- CACNB2 | c.1870C>T p.Q624* (on ENST00000324631 / NM_201596.3; = p.Q569* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 57/161 reads (35%) | called by muse, mutect2, varscan2
- CACNB4 | c.803G>T p.R268M | Missense Mutation (SNP) | VAF 83/324 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CALCR | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- CAMK1G | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAPN10 | c.1556T>G p.L519R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CAPZA3 | c.394C>A p.H132N | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CARD11 | c.1483C>A p.P495T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CASP4 | c.995A>T p.K332I | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CATSPERG | c.1475G>T p.W492L | Missense Mutation (SNP) | VAF 93/302 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CCDC136 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CCDC148 | c.1133A>T p.Q378L | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC24 | c.-33+3G>A | Splice Region (SNP) | VAF 36/111 reads (32%) | called by muse, mutect2, varscan2
- CCDC40 | c.2032A>T p.T678S | Missense Mutation (SNP) | VAF 127/256 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CCDC88B | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CCK | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- CCR2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CCR7 | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CD33 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CDC42BPA | c.2535G>T p.M845I | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CDH18 | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 99/411 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CDH20 | c.349C>G p.H117D | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CDH9 | c.2087C>G p.T696S | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDHR2 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- CDHR3 | c.2272+1G>T p.X758_splice | Splice Site (SNP) | VAF 71/323 reads (22%) | called by muse, mutect2, varscan2
- CENPE | c.3367G>T p.A1123S | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, varscan2
- CENPV | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.441); called by muse, varscan2
- CEP162 | c.604G>T p.V202F | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CEP192 | c.6659A>G p.Q2220R | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- CEP250 | c.2402A>T p.K801M | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CEP290 | c.5423G>T p.S1808I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); called by muse, varscan2
- CEP290 | c.3309+5G>A | Splice Region (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- CERS3 | c.244G>C p.V82L | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- CETN3 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CFAP206 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); called by muse, varscan2
- CFAP20DC | c.928G>T p.E310* (on ENST00000482387 / NM_001351530.2; = p.E185* on NM_198463.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 48/242 reads (20%) | called by muse, mutect2, varscan2
- CFAP44 | c.5375del p.G1792Afs*21 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by mutect2, pindel, varscan2
- CFAP44 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CFAP65 | c.5380del p.E1794Rfs*2 | Frame Shift Del (DEL) | VAF 115/571 reads (20%) | called by pindel, varscan2
- CFAP65 | c.5372G>C p.G1791A | Missense Mutation (SNP) | VAF 146/568 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.015); called by muse, varscan2
- CFAP70 | c.741C>A p.F247L | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CFH | c.2319T>G p.H773Q | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHAT | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 165/631 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD1 | c.2213G>T p.S738I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, varscan2
- CHD4 | c.2600A>T p.N867I (on ENST00000357008 / NM_001363606.2; = p.N880I on NM_001273.5) | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CHIT1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 216/861 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, varscan2
- CHL1 | c.2238G>T p.E746D (on ENST00000397491 / NM_001253387.1; = p.E762D on NM_006614.4) | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CHST13 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CHST8 | c.95A>T p.Q32L | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CHURC1 | c.336_337delinsT p.M113Cfs*23 (on ENST00000549115 / NM_001204063.1; = p.M114Cfs*23 on NM_145165.3) | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | called by pindel, varscan2*
- CLCA2 | c.2018C>A p.S673* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- CLEC9A | c.528del p.L177Cfs*38 | Frame Shift Del (DEL) | VAF 51/233 reads (22%) | called by mutect2, pindel, varscan2
- CNGB3 | c.624C>A p.N208K | Missense Mutation (SNP) | VAF 155/410 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNKSR2 | c.1485G>T p.K495N | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, varscan2
- CNKSR2 | c.1575G>T p.M525I | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- CNOT2 | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CNOT4 | c.1500G>T p.W500C (on ENST00000315544 / NM_001190848.1; = p.W497C on NM_013316.4) | Missense Mutation (SNP) | VAF 113/427 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CNTN4 | c.2503G>A p.G835S | Missense Mutation (SNP) | VAF 93/392 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CNTN5 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 110/907 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- COBLL1 | c.2965G>T p.E989* (on ENST00000392717; = p.E951* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 84/379 reads (22%) | called by muse, mutect2, varscan2
- COL11A1 | c.3241G>T p.G1081C | Missense Mutation (SNP) | VAF 105/617 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A2 | c.2188G>T p.G730C (on ENST00000341947 / NM_080680.3; = p.G623C on NM_080679.2) | Missense Mutation (SNP) | VAF 148/679 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL12A1 | c.7210+1G>T p.X2404_splice | Splice Site (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- COL14A1 | c.4211G>T p.R1404I | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL15A1 | c.2366C>A p.P789H | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL15A1 | c.3575del p.P1192Lfs*32 | Frame Shift Del (DEL) | VAF 94/322 reads (29%) | called by mutect2, pindel, varscan2
- COL20A1 | c.1091C>A p.P364Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- COL22A1 | c.3760C>A p.P1254T | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- COL22A1 | c.2646+1G>T p.X882_splice | Splice Site (SNP) | VAF 57/352 reads (16%) | called by muse, varscan2
- COL6A1 | c.2111G>T p.G704V | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.3316G>C p.G1106R | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL6A6 | c.563C>A p.T188K | Missense Mutation (SNP) | VAF 73/383 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- COLQ | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COP1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); called by muse, varscan2
- COPS8 | c.265A>C p.I89L | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CPA6 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPQ | c.698G>T p.C233F | Missense Mutation (SNP) | VAF 65/385 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CPS1 | c.1549G>T p.G517* | Nonsense Mutation (SNP) | VAF 45/261 reads (17%) | called by muse, mutect2, varscan2
- CPS1 | c.1634_1636delinsCA p.E545Afs*10 | Frame Shift Del (DEL) | VAF 19/147 reads (13%) | called by pindel, varscan2*
- CREBBP | c.6530G>T p.G2177V | Missense Mutation (SNP) | VAF 198/560 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CRISPLD1 | c.1220A>T p.H407L | Missense Mutation (SNP) | VAF 89/279 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CROCC | c.5689G>T p.V1897L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CRX | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRYAB | c.209T>A p.L70Q | Missense Mutation (SNP) | VAF 189/759 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CRYBG3 | c.1570G>C p.V524L | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CSMD1 | c.5213G>A p.S1738N (on ENST00000520002; = p.S1737N on NM_033225.6) | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CSMD3 | c.10183C>A p.P3395T (on ENST00000297405 / NM_001363185.1; = p.P3226T on NM_052900.3) | Missense Mutation (SNP) | VAF 181/463 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CSMD3 | c.9875G>T p.G3292V (on ENST00000297405 / NM_001363185.1; = p.G3123V on NM_052900.3) | Missense Mutation (SNP) | VAF 132/345 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.6848G>A p.C2283Y (on ENST00000297405 / NM_001363185.1; = p.C2179Y on NM_052900.3) | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- CSPG4 | c.2868G>T p.M956I | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSRNP3 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- CTNND2 | c.915C>A p.S305R | Missense Mutation (SNP) | VAF 95/341 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- CUBN | c.9048C>A p.N3016K | Missense Mutation (SNP) | VAF 199/726 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- CUTA | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CWH43 | c.1034C>A p.A345D | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- CYB5R4 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CYP21A2 | c.1079T>A p.V360E | Missense Mutation (SNP) | VAF 206/1929 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CYP27C1 | c.572G>T p.W191L | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- CYP27C1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYTH1 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 122/233 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DACH1 | c.1097C>A p.S366Y | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- DAZL | c.730C>G p.Q244E | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- DBH | c.1515C>G p.S505R | Missense Mutation (SNP) | VAF 149/438 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DBH | c.1622C>G p.S541C | Missense Mutation (SNP) | VAF 151/367 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- DBX2 | c.827G>A p.C276Y | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- DCAF4L2 | c.1175T>A p.F392Y | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DCHS1 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCLRE1C | c.1155A>T p.S385= (on ENST00000378278 / NM_001350965.2; = p.S270= on NM_022487.4) | Splice Region (SNP) | VAF 96/633 reads (15%) | called by muse, mutect2, varscan2
- DDX25 | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DELE1 | c.437G>T p.S146I | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DENND1B | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DGKB | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKG | c.769G>C p.V257L | Missense Mutation (SNP) | VAF 190/442 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DHTKD1 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DHX57 | c.1588-1G>T p.X530_splice | Splice Site (SNP) | VAF 57/233 reads (24%) | called by muse, mutect2, varscan2
- DIO3 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DIP2A | c.2663G>A p.G888D | Missense Mutation (SNP) | VAF 95/444 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DIPK2A | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 104/432 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DISP3 | c.1829C>A p.P610H | Missense Mutation (SNP) | VAF 105/386 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLC1 | c.3406G>T p.V1136F (on ENST00000276297 / NM_001348081.2; = p.V699F on NM_006094.5) | Missense Mutation (SNP) | VAF 131/459 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- DLGAP2 | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- DLGAP3 | c.880G>C p.G294R | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- DLL3 | c.1244G>T p.C415F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- DMBT1 | c.3317G>T p.W1106L (on ENST00000338354 / NM_001377530.1; = p.W607L on NM_004406.3) | Missense Mutation (SNP) | VAF 49/492 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DNAAF6 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.033); called by muse, varscan2
- DNAH10 | c.2645G>T p.R882M (on ENST00000409039; = p.R821M on NM_207437.3) | Missense Mutation (SNP) | VAF 112/311 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- DNAH12 | c.7695G>T p.M2565I (on ENST00000351747; = p.M3433I on NM_001366028.2) | Missense Mutation (SNP) | VAF 96/467 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DNAH3 | c.3011T>A p.L1004Q | Missense Mutation (SNP) | VAF 114/301 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.10796C>A p.T3599K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.862); called by muse, mutect2
- DNAI3 | c.1284_1285insT p.A429Cfs*10 | Frame Shift Ins (INS) | VAF 24/107 reads (22%) | called by mutect2, pindel*, varscan2
- DPYD | c.193A>C p.T65P | Missense Mutation (SNP) | VAF 117/342 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DPYSL5 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSP | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DSPP | c.3254G>T p.S1085I | Missense Mutation (SNP) | VAF 375/844 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, varscan2
- EBF3 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- EDIL3 | c.680C>A p.T227N | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EDN3 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- EFCAB6 | c.4282A>T p.I1428F | Missense Mutation (SNP) | VAF 181/444 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EFHC2 | c.2189C>A p.P730H | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ELOVL5 | c.342G>T p.W114C | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EML1 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 74/255 reads (29%) | called by muse, mutect2, varscan2
- EMP2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- EMSY | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EMSY | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- EN1 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ENO4 | c.295A>T p.K99* (on ENST00000622726; = p.K98* on NM_001242699.2) | Nonsense Mutation (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- ENPEP | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ENPP2 | c.676C>A p.H226N | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- ENPP3 | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ENTPD4 | c.916A>T p.N306Y | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENTPD4 | c.411G>T p.P137= | Splice Region (SNP) | VAF 60/156 reads (38%) | called by muse, mutect2
- EPS8L3 | c.793A>T p.R265W | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ESPNL | c.1164G>T p.M388I | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ETNPPL | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- ETS1 | c.1100A>T p.D367V | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EXT1 | c.2128A>T p.S710C | Missense Mutation (SNP) | VAF 192/417 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- EXT1 | c.1459del p.V487* | Frame Shift Del (DEL) | VAF 137/396 reads (35%) | called by mutect2, pindel, varscan2
- F13B | c.1259C>G p.S420* | Nonsense Mutation (SNP) | VAF 54/272 reads (20%) | called by muse, mutect2, varscan2
- FAM126A | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- FAM167A | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM170B | c.17C>G p.T6R | Missense Mutation (SNP) | VAF 105/348 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM171B | c.283C>A p.R95S | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- FAM43A | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FAM83B | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- FAM90A1 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 201/1316 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- FAP | c.769G>C p.A257P | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FASN | c.986T>A p.M329K | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT1 | c.4891G>T p.A1631S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT3 | c.7335C>A p.D2445E | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FBL | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FBXO33 | c.600-2A>T p.X200_splice | Splice Site (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- FCHSD1 | c.377del p.G126Efs*19 | Frame Shift Del (DEL) | VAF 65/202 reads (32%) | called by mutect2, pindel, varscan2
- FER1L6 | c.3563G>T p.R1188M | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- FERD3L | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 118/460 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- FGA | c.2404G>T p.V802F | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FGF10 | c.371A>T p.K124I | Missense Mutation (SNP) | VAF 116/457 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FGF14 | c.60C>A p.H20Q | Missense Mutation (SNP) | VAF 154/385 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FGGY | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 106/403 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2
- FLNC | c.4128-1G>T p.X1376_splice | Splice Site (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- FMNL3 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 102/406 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FMR1 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- FNDC1 | c.5552C>A p.A1851D | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- FOXF2 | c.1080C>A p.N360K | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FOXI1 | c.78del p.E27Rfs*2 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- FREM2 | c.8719G>T p.G2907C | Missense Mutation (SNP) | VAF 113/263 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSTL4 | c.1874A>T p.D625V | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FZD5 | c.1681G>C p.A561P | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- G2E3 | c.1477G>C p.D493H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GABRA5 | c.579C>A p.S193R | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GABRA6 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 105/360 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRB3 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 233/652 reads (36%) | called by muse, mutect2, varscan2
- GABRG2 | c.605_613delinsTCCT p.H202Lfs*35 (on ENST00000361925 / NM_001375343.1; = p.H202Lfs*13 on NM_000816.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 47/208 reads (23%) | called by pindel, varscan2*
- GABRR3 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GALNT17 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, varscan2
- GAREM1 | c.2431C>T p.L811F (on ENST00000269209 / NM_001242409.2; = p.L810F on NM_022751.3) | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- GBA3 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- GBP4 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GBP6 | c.1580T>A p.I527K | Missense Mutation (SNP) | VAF 95/339 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GCKR | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- GDF6 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 131/816 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GEN1 | c.2341G>T p.V781F | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GET1 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GFRA4 | c.764C>A p.P255Q (on ENST00000319242 / NM_145762.3; = p.P225Q on NM_022139.4) | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GIPC2 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- GLG1 | c.1127G>C p.C376S | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLT8D2 | c.436A>T p.I146F | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- GMIP | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GNG3 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 126/535 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, varscan2
- GOLGA6L10 | c.232C>G p.R78G | Missense Mutation (SNP) | VAF 86/858 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- GP5 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- GPA33 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- GPCPD1 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPD2 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 68/262 reads (26%) | called by muse, mutect2, varscan2
- GPI | c.841G>C p.G281R | Missense Mutation (SNP) | VAF 170/647 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GPI | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 172/654 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GPR158 | c.2066T>A p.M689K | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- GPR33 | c.892C>A p.L298I | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- GRID2 | c.2783C>A p.T928N | Missense Mutation (SNP) | VAF 56/453 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GRIN2B | c.3992T>A p.M1331K | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- GSTM2 | c.643C>G p.Q215E | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCY1A2 | c.1348C>G p.R450G | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HABP2 | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HAT1 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, varscan2
- HDAC1 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HECW1 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 80/469 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- HERC2 | c.12258G>T p.E4086D | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HES3 | c.529C>G p.P177A | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HEYL | c.334dup p.L112Pfs*4 | Frame Shift Ins (INS) | VAF 20/83 reads (24%) | called by mutect2, pindel, varscan2
- HIPK2 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 126/431 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- HIPK4 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- HLX | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 90/416 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HMCN1 | c.7088G>C p.C2363S | Missense Mutation (SNP) | VAF 64/292 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HOXA13 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 60/619 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- HOXA4 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 165/554 reads (30%) | called by muse, mutect2, varscan2
- HSD17B14 | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSD3B1 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
1,221 further variants in this file (598 protein-altering or splice-affecting, 376 silent, 247 other) are not listed here.
